Somatic mutation profile of tumor specimen C3N-02435-01 (aliquot CPT0241170006) from CPTAC case C3N-02435, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 64.4 years (23,531 days).
Specimen C3N-02435-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9da1728-4894-4f65-9e50-dace37880c80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02435-31 (Blood Derived Normal), aliquot CPT0241820002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fabafa02-ccca-42ac-b31a-9383dd302a01

The open-access MAF lists 361 somatic variants for this specimen: 246 protein-altering or splice-affecting, 67 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 202, Silent 67, Intron 19, Nonsense Mutation 17, 5'UTR 12, Frame Shift Del 10, Splice Site 8, RNA 8, 5'Flank 5, Frame Shift Ins 4, Splice Region 4, 3'UTR 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MMUT | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs772552898, CM050683, COSV99222325; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 99/242 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs121909238, CM051214, COSV100910602, COSV64296545, COSV64296755; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLCO2A1 | c.1807C>T p.R603* | Nonsense Mutation (SNP) | VAF 7/75 reads (9%) | catalogued as rs776813259, CM1311291; ClinVar: pathogenic; called by muse, mutect2
- ACSM5 | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 33/211 reads (16%) | catalogued as rs780288053; called by muse, mutect2, varscan2
- ADGRG6 | c.1896G>A p.M632I | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as rs769911718; called by muse, mutect2
- AHNAK | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 82/220 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.116); catalogued as rs777135489; called by muse, mutect2, varscan2
- AMER1 | c.3038C>T p.P1013L | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs765991551; called by muse, mutect2, varscan2
- ANTXRL | c.181C>A p.H61N | Missense Mutation (SNP) | VAF 119/286 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.242); catalogued as rs1554955540; called by muse, mutect2, varscan2
- APOBEC3F | c.525C>A p.D175E | Missense Mutation (SNP) | VAF 73/249 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs527685670; called by muse, mutect2, varscan2
- ATP9B | c.310A>G p.I104V | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs777060597; called by muse, varscan2
- BICC1 | c.2491G>T p.A831S | Missense Mutation (SNP) | VAF 70/277 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99570044; called by muse, mutect2, varscan2
- BRWD3 | c.5132G>A p.R1711K | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.05); catalogued as COSV64749162; called by muse, mutect2, varscan2
- BSN | c.9977G>A p.R3326K | Missense Mutation (SNP) | VAF 46/351 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.056); catalogued as rs376386796; called by muse, mutect2, varscan2
- CACNA2D1 | c.2611-1G>T p.X871_splice (on ENST00000356253 / NM_001366867.1; = p.X859_splice on NM_000722.4) | Splice Site (SNP) | VAF 23/90 reads (26%) | catalogued as COSV100666588; called by muse, mutect2, varscan2
- CDK15 | c.592C>G p.P198A (on ENST00000652192 / NM_001366386.2; = p.P147A on NM_139158.2) | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as rs1179844780; called by muse, mutect2, varscan2
- CHST7 | c.20G>C p.R7P | Missense Mutation (SNP) | VAF 60/359 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as rs1247550163, COSV99333011; called by muse, mutect2, varscan2
- CNGA2 | c.589+1G>A p.X197_splice | Splice Site (SNP) | VAF 23/122 reads (19%) | catalogued as COSV61705129; called by muse, mutect2, varscan2
- COL6A6 | c.4276G>C p.E1426Q | Missense Mutation (SNP) | VAF 17/241 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.511); catalogued as rs1330919244; called by muse, mutect2
- CSH2 | c.10+6C>T | Splice Region (SNP) | VAF 46/308 reads (15%) | catalogued as rs780794922; called by muse, mutect2, varscan2
- CUL9 | c.2932G>A p.G978R | Missense Mutation (SNP) | VAF 108/522 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as rs1023703620; called by muse, mutect2, varscan2
- CYP2C9 | c.1240G>C p.D414H | Missense Mutation (SNP) | VAF 14/323 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV99582233; called by muse, mutect2
- DENND2A | c.2207C>G p.S736C | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs753667814; called by muse, mutect2, varscan2
- DMD | c.3921T>C p.D1307= | Splice Region (SNP) | VAF 40/175 reads (23%) | catalogued as rs753416782; called by muse, mutect2, varscan2
- DNAAF3 | c.214C>T p.R72C (on ENST00000524407 / NM_001256715.2; = p.R119C on NM_178837.4) | Missense Mutation (SNP) | VAF 60/591 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs750438145; called by muse, mutect2, varscan2
- EFCAB5 | c.3766C>T p.R1256C | Missense Mutation (SNP) | VAF 70/282 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs190450097, COSV57926515; called by muse, mutect2, varscan2
- ENGASE | c.364A>T p.R122W | Missense Mutation (SNP) | VAF 127/435 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1400016278; called by muse, mutect2, varscan2
- ENGASE | c.365G>T p.R122M | Missense Mutation (SNP) | VAF 124/431 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs1445075832; called by muse, mutect2, varscan2
- ERI1 | c.699G>T p.W233C | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1171572202, COSV99141425; called by muse, mutect2, varscan2
- FREM2 | c.5984G>T p.G1995V | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV99751534; called by muse, mutect2, varscan2
- GPR88 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 14/381 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); catalogued as rs1182577646, COSV59291692; called by muse, mutect2
- HECTD4 | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as rs868718215; called by muse, mutect2, varscan2
- HIVEP3 | c.5248G>T p.G1750C | Missense Mutation (SNP) | VAF 95/320 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56025664; called by muse, mutect2, varscan2
- HYDIN | c.12850A>G p.T4284A | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1220445991; called by mutect2, varscan2
- IBSP | c.847G>T p.G283W | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56894557; called by muse, mutect2, varscan2
- IMPG1 | c.25A>G p.I9V | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1382214932; called by muse, mutect2
- KCNG4 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as rs772484443, COSV57583317; called by muse, mutect2, varscan2
- KIAA1549L | c.1135A>G p.M379V (on ENST00000321505; = p.M676V on NM_012194.3) | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1349458688; called by muse, mutect2, varscan2
- KIF20B | c.1711G>C p.E571Q | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV99590593; called by muse, varscan2
- L3MBTL1 | c.1498C>A p.L500I (on ENST00000418998 / NM_001377303.1; = p.L410I on NM_015478.7) | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64229120; called by muse, mutect2, varscan2
- LGR4 | c.2299dup p.S767Ffs*43 | Frame Shift Ins (INS) | VAF 28/104 reads (27%) | catalogued as rs1229958149; called by mutect2, varscan2
- LINGO2 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58060155, COSV58063806; called by muse, mutect2, varscan2
- LRIG3 | c.2948G>A p.R983Q | Missense Mutation (SNP) | VAF 43/244 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs753738730; called by muse, mutect2, varscan2
- LRRC4B | c.1388G>A p.G463D | Missense Mutation (SNP) | VAF 25/312 reads (8%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.931); catalogued as rs749356572; called by muse, mutect2
- LRRC4C | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 86/243 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV53433104; called by muse, mutect2, varscan2
- LTA | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs1385681949, COSV101403219; called by muse, mutect2, varscan2
- MAGEB1 | c.578G>A p.W193* | Nonsense Mutation (SNP) | VAF 21/189 reads (11%) | catalogued as COSV100974984; called by muse, mutect2, varscan2
- MAGEB6 | c.1039G>T p.V347L | Missense Mutation (SNP) | VAF 59/249 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as rs954342921, COSV99081185; called by muse, mutect2, varscan2
- MAP4K3 | c.1957G>T p.D653Y | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55715457; called by muse, mutect2, varscan2
- MTMR1 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs990248555, COSV64892695; called by muse, mutect2, varscan2
- MUC2 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 138/407 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs541501827; called by muse, mutect2, varscan2
- MXRA5 | c.1651G>A p.G551S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54238399; called by muse, varscan2
- MYO5C | c.2254C>T p.R752* | Nonsense Mutation (SNP) | VAF 24/115 reads (21%) | catalogued as rs764090555, COSV55903246; called by muse, mutect2, varscan2
- NOTCH2 | c.4503G>C p.K1501N | Missense Mutation (SNP) | VAF 126/472 reads (27%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.505); catalogued as COSV56709662; called by muse, mutect2, varscan2
- NT5DC1 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs1387039410; called by muse, mutect2
- OBSCN | c.9976A>G p.M3326V | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769644250; called by muse, mutect2, varscan2
- ODF3 | c.318C>G p.Y106* | Nonsense Mutation (SNP) | VAF 40/241 reads (17%) | catalogued as COSV57293320; called by muse, mutect2, varscan2
- OR11H2 | c.556G>C p.G186R (on ENST00000556246; = p.G197R on NM_001197287.1) | Missense Mutation (SNP) | VAF 100/1487 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73703671; called by muse, mutect2
- OR13C4 | c.322G>T p.G108W | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52927102, COSV52928603; called by muse, mutect2
- OR4K2 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 32/296 reads (11%) | catalogued as rs1160415899; called by muse, varscan2
- OTOGL | c.3902C>T p.S1301L (on ENST00000547103; = p.S1292L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV101509530; called by muse, mutect2, varscan2
- PCDHGA7 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as COSV54049029; called by muse, varscan2
- PCDHGA8 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 74/421 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs747606142; called by muse, mutect2, varscan2
- PDZD4 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs782383096, COSV51246281; called by muse, mutect2, varscan2
- PHEX | c.1573G>A p.V525I | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs879138132; called by muse, mutect2
- PHLPP1 | c.3604C>T p.R1202C | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs760057011, COSV53027309; called by muse, mutect2, varscan2
- POU6F2 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs747165081; called by muse, mutect2, varscan2
- PPFIA2 | c.2875C>A p.Q959K | Missense Mutation (SNP) | VAF 111/337 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV61024597; called by muse, mutect2, varscan2
- PRDM9 | c.334C>G p.Q112E | Missense Mutation (SNP) | VAF 368/633 reads (58%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.036); catalogued as rs1487956793; called by muse, mutect2, varscan2
- RDH12 | c.904C>A p.R302S | Missense Mutation (SNP) | VAF 187/469 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as COSV50821372; called by muse, mutect2, varscan2
- RGPD3 | c.2863C>T p.R955W | Missense Mutation (SNP) | VAF 101/880 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs567422835; called by muse, mutect2, varscan2
- RIT2 | c.192C>A p.D64E | Missense Mutation (SNP) | VAF 79/239 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1280601502; called by muse, mutect2, varscan2
- RNF217 | c.92C>G p.P31R | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.01); catalogued as rs1176626480; called by muse, mutect2, varscan2
- SHOX2 | c.557T>C p.V186A (on ENST00000441443 / NM_006884.3; = p.V210A on NM_003030.4) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV67463426, COSV67463728, COSV67464226; called by muse, mutect2, varscan2
- SLC5A2 | c.198+6A>T | Splice Region (SNP) | VAF 105/552 reads (19%) | catalogued as rs747772485; called by muse, mutect2, varscan2
- SRSF6 | c.866T>C p.I289T | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs779384024; called by muse, mutect2, varscan2
- STOML1 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs768236910; called by muse, mutect2, varscan2
- TACC2 | c.5738C>T p.S1913L | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs377123555; called by muse, mutect2, varscan2
- TAF4B | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs758560400, COSV99300120; called by muse, mutect2
- TAZ | c.521G>C p.W174S | Missense Mutation (SNP) | VAF 43/493 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54797267; called by muse, mutect2
- TIMP3 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 126/472 reads (27%) | catalogued as COSV99831273; called by muse, mutect2
- TP53 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 112/228 reads (49%) | catalogued as COSV52771366, COSV52826932, COSV52883452; called by muse, mutect2, varscan2
- TRHDE | c.1313T>C p.I438T | Missense Mutation (SNP) | VAF 86/184 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs1261206616; called by muse, mutect2, varscan2
- TRIM43 | c.508-2A>C p.X170_splice | Splice Site (SNP) | VAF 91/433 reads (21%) | catalogued as rs1306743417; called by muse, mutect2, varscan2
- WAS | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as CD096363; called by muse, mutect2, varscan2
- ZFP62 | c.1469C>G p.S490C (on ENST00000502412 / NM_001377944.1; = p.S457C on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1208475216; called by muse, mutect2, varscan2
- ZNF385B | c.1420A>G p.I474V | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.044); catalogued as rs1413597404; called by muse, mutect2
- ABCB1 | c.3334C>A p.H1112N | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ACSS1 | c.1192G>T p.G398C | Missense Mutation (SNP) | VAF 91/345 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ACVR1 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 44/274 reads (16%) | called by muse, mutect2, varscan2
- ADAD1 | c.140C>A p.S47Y | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- ADGRF4 | c.1441C>A p.H481N | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKEF1 | c.1058G>A p.S353N | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- ANO6 | c.2521A>T p.M841L | Missense Mutation (SNP) | VAF 65/433 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- AP4E1 | c.1811A>G p.K604R | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AQR | c.2641C>T p.H881Y | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- ARID1A | c.1113dup p.Q372Afs*28 | Frame Shift Ins (INS) | VAF 23/114 reads (20%) | called by mutect2, pindel, varscan2
- ASPH | c.926T>C p.V309A | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2
- ATP5MC3 | c.174G>C p.R58S | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- BBS7 | c.1283G>C p.S428T | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- BCL6 | c.902A>T p.K301I | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BHLHE23 | c.106G>A p.A36T (on ENST00000370346; = p.A52T on NM_080606.4) | Missense Mutation (SNP) | VAF 53/258 reads (21%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRWD3 | c.2181G>A p.M727I | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- BTBD8 | c.5073A>T p.Q1691H (on ENST00000636805 / NM_001376131.1; = p.Q1178H on NM_015237.4) | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- BTLA | c.65A>G p.Y22C | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- CACHD1 | c.1921T>C p.C641R | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- CALCA | c.412del p.Q138Rfs*22 | Frame Shift Del (DEL) | VAF 110/398 reads (28%) | called by mutect2, pindel, varscan2
- CARMIL3 | c.3302G>C p.G1101A | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- CCDC158 | c.923C>G p.A308G | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCL15 | c.152_154del p.A51del | In Frame Del (DEL) | VAF 90/374 reads (24%) | called by pindel, varscan2
- CCNB3 | c.1371G>T p.L457F | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CD109 | c.778G>T p.V260L | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- CD1E | c.955C>A p.L319M | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP47 | c.9354G>C p.Q3118H | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.204); called by muse, mutect2
- CGN | c.1568A>T p.Q523L | Missense Mutation (SNP) | VAF 47/229 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- COL6A5 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CUL4A | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 24/297 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.865); called by muse, mutect2
- DACH2 | c.311del p.G104Efs*10 | Frame Shift Del (DEL) | VAF 69/239 reads (29%) | called by mutect2, pindel, varscan2
- DCAF8L2 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- DCTN1 | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 180/577 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- DDR1 | c.566-2A>T p.X189_splice | Splice Site (SNP) | VAF 42/99 reads (42%) | called by muse, mutect2, varscan2
- DNHD1 | c.11103A>T p.E3701D | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- DROSHA | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 86/420 reads (20%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.13594A>G p.N4532D | Missense Mutation (SNP) | VAF 24/606 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2
- ELMOD1 | c.222del p.D75Tfs*7 | Frame Shift Del (DEL) | VAF 11/100 reads (11%) | called by mutect2, pindel, varscan2
- FAM186A | c.5378A>T p.Q1793L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- FBXW12 | c.195G>A p.W65* | Nonsense Mutation (SNP) | VAF 37/91 reads (41%) | called by muse, mutect2, varscan2
- FLNA | c.6366C>A p.D2122E (on ENST00000369850 / NM_001110556.2; = p.D2114E on NM_001456.3) | Missense Mutation (SNP) | VAF 104/422 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- FREM3 | c.1465G>T p.G489W | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- FRMPD3 | c.3476G>T p.R1159L | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.053); called by muse, mutect2
- GFRAL | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 93/287 reads (32%) | called by muse, mutect2, varscan2
- GK | c.1391G>T p.G464V (on ENST00000427190 / NM_001205019.2; = p.G458V on NM_000167.6) | Missense Mutation (SNP) | VAF 83/437 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLIS3 | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.011); called by muse, varscan2
- GOLGA6L7 | c.170C>G p.S57W | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GUCY2C | c.1145T>C p.L382P | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- HCFC1 | c.1967G>T p.G656V | Missense Mutation (SNP) | VAF 58/310 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- HCN3 | c.2230C>T p.L744F | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- HGF | c.284A>T p.Q95L | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- HINT3 | c.244A>T p.T82S | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- HKDC1 | c.1766G>T p.G589V | Missense Mutation (SNP) | VAF 99/235 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSF5 | c.1071G>T p.W357C | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INO80 | c.3435G>A p.M1145I | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ITGA8 | c.2637+2T>G p.X879_splice | Splice Site (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- ITIH6 | c.2521G>T p.G841W | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- JPH2 | c.1635C>G p.I545M | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- KLHL36 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 61/222 reads (27%) | called by muse, mutect2, varscan2
- KLK4 | c.627dup p.P210Afs*36 | Frame Shift Ins (INS) | VAF 120/667 reads (18%) | called by mutect2, pindel, varscan2
- LAMA4 | c.1406C>G p.T469S (on ENST00000230538 / NM_001105206.3; = p.T462S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/314 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMP2 | c.915G>T p.L305F | Missense Mutation (SNP) | VAF 71/420 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.029); called by muse, mutect2
- LEPR | c.1401T>C p.H467= | Splice Region (SNP) | VAF 84/392 reads (21%) | called by muse, mutect2, varscan2
- LEPR | c.3457C>T p.H1153Y | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2
- LIG4 | c.970C>G p.Q324E | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRC43 | c.1009A>C p.T337P | Missense Mutation (SNP) | VAF 49/267 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- LRRIQ1 | c.2067C>A p.N689K | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRK2 | c.1750G>T p.G584C | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTA | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 39/269 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- MAGEH1 | c.160G>C p.D54H | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- MAGEH1 | c.161A>T p.D54V | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MCCC1 | c.1655A>C p.N552T | Missense Mutation (SNP) | VAF 9/215 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.011); called by muse, mutect2
- ME2 | c.907T>G p.S303A | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MEGF10 | c.1637A>T p.H546L | Missense Mutation (SNP) | VAF 122/281 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- MEIS1 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 40/402 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MIA2 | c.1909C>G p.P637A | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- MN1 | c.2586G>T p.Q862H | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MPP5 | c.840T>G p.I280M | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- MSL3 | c.720G>A p.M240I (on ENST00000312196 / NM_078629.4; = p.M74I on NM_006800.4) | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.025); called by muse, mutect2
- MUC20 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 27/993 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- MYB | c.1908del p.T637Rfs*20 | Frame Shift Del (DEL) | VAF 91/267 reads (34%) | called by mutect2, pindel, varscan2
- MYO5C | c.4799G>A p.C1600Y | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); called by muse, mutect2
- NAV3 | c.6502C>G p.L2168V (on ENST00000397909 / NM_001024383.2; = p.L2146V on NM_014903.6) | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2
- NEIL1 | c.952dup p.S318Kfs*16 | Frame Shift Ins (INS) | VAF 55/229 reads (24%) | called by mutect2, pindel, varscan2
- NELL1 | c.82C>A p.L28I | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.133); called by muse, mutect2
- NLGN3 | c.2362G>T p.A788S (on ENST00000358741 / NM_181303.2; = p.A768S on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 139/489 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NLRP12 | c.2408T>A p.M803K | Missense Mutation (SNP) | VAF 148/637 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- NLRP3 | c.1444T>G p.F482V | Missense Mutation (SNP) | VAF 58/235 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NLRP5 | c.35C>A p.A12D | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NUP42 | c.826T>A p.S276T | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- OR1D2 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 96/180 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- OR2B11 | c.10G>T p.D4Y | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- OR52B2 | c.513C>A p.C171* | Nonsense Mutation (SNP) | VAF 80/225 reads (36%) | called by muse, mutect2, varscan2
- PCDH15 | c.4907C>T p.P1636L | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT tolerated, low confidence (0.15); called by muse, mutect2, varscan2
- PDPR | c.2404A>G p.S802G | Missense Mutation (SNP) | VAF 86/375 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- PIK3C2A | c.1918C>G p.P640A | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- PJA1 | c.1088A>G p.E363G (on ENST00000361478 / NM_145119.4; = p.E175G on NM_022368.5) | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- PLA2G5 | c.377A>T p.N126I | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- PLEKHA6 | c.3128G>T p.S1043I | Missense Mutation (SNP) | VAF 56/315 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PM20D2 | c.161A>G p.E54G | Missense Mutation (SNP) | VAF 69/405 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- PMM1 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- PMP2 | c.23C>A p.T8N | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PPP1R10 | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PPP1R3F | c.587C>G p.A196G | Missense Mutation (SNP) | VAF 30/520 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); called by muse, mutect2
- PRDM2 | c.2143G>T p.G715C | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PRKX | c.857_860del p.R286Qfs*4 | Frame Shift Del (DEL) | VAF 18/192 reads (9%) | called by mutect2, pindel, varscan2
- PRR12 | c.1552G>T p.G518* (on ENST00000615927; = p.G1339* on NM_020719.3) | Nonsense Mutation (SNP) | VAF 43/131 reads (33%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.2872G>C p.A958P | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASGRP4 | c.177T>A p.D59E | Missense Mutation (SNP) | VAF 199/577 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RECK | c.2843G>T p.R948M | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RNF38 | c.79A>G p.R27G | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RNF40 | c.2140G>A p.D714N | Missense Mutation (SNP) | VAF 13/295 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2
- RPIA | c.319A>G p.T107A | Missense Mutation (SNP) | VAF 142/532 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- RPS4X | c.322C>A p.R108S | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- RTRAF | c.532-2A>G p.X178_splice | Splice Site (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2, varscan2
- SAA2 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 70/230 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- SAFB | c.2135G>A p.R712Q | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SBK2 | c.979C>A p.R327S | Missense Mutation (SNP) | VAF 114/369 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SCARA5 | c.560A>G p.Q187R | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHROOM2 | c.979G>C p.A327P | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SKOR1 | c.2803G>T p.E935* | Nonsense Mutation (SNP) | VAF 70/252 reads (28%) | called by muse, mutect2, varscan2
- SLC10A4 | c.1250_1257del p.T417Rfs*41 | Frame Shift Del (DEL) | VAF 21/78 reads (27%) | called by mutect2, pindel, varscan2
- SLC12A7 | c.1187C>A p.P396H | Missense Mutation (SNP) | VAF 40/609 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- SLC35D3 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 36/323 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC35G5 | c.952G>T p.G318C | Missense Mutation (SNP) | VAF 54/426 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, varscan2
- SLC35G5 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 54/424 reads (13%) | SIFT tolerated (0.96); PolyPhen probably damaging (1); called by muse, varscan2
- SLITRK3 | c.1526T>C p.L509P | Missense Mutation (SNP) | VAF 109/363 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SNRNP200 | c.856del p.A286Qfs*8 | Frame Shift Del (DEL) | VAF 122/470 reads (26%) | called by mutect2, pindel, varscan2
- SPDEF | c.364del p.V122Cfs*94 | Frame Shift Del (DEL) | VAF 104/348 reads (30%) | called by mutect2, pindel, varscan2
- SPHKAP | c.4513G>A p.E1505K | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- STIMATE | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 93/249 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- STRIP2 | c.584A>G p.D195G | Missense Mutation (SNP) | VAF 53/233 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SUPT20HL1 | c.1993G>T p.A665S | Missense Mutation (SNP) | VAF 60/390 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SYT1 | c.359A>G p.K120R | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TAT | c.283del p.Q95Rfs*3 | Frame Shift Del (DEL) | VAF 70/497 reads (14%) | called by mutect2, pindel, varscan2
- TBC1D25 | c.1466C>A p.A489D | Missense Mutation (SNP) | VAF 17/272 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.02); called by muse, mutect2
- TEX2 | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.193); called by muse, mutect2
- THSD7A | c.3883del p.W1295Gfs*14 | Frame Shift Del (DEL) | VAF 30/196 reads (15%) | called by mutect2, pindel, varscan2
- TIMM8A | c.211A>T p.I71F | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- TMEM63C | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TMTC4 | c.967T>C p.S323P (on ENST00000376234 / NM_001350577.2; = p.S342P on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.427); called by muse, mutect2
- TNRC18 | c.2384C>T p.P795L | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRAPPC11 | c.2964-2A>T p.X988_splice | Splice Site (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- TTN | c.42115G>A p.E14039K (on ENST00000591111; = p.E6615K on NM_003319.4) | Missense Mutation (SNP) | VAF 16/456 reads (4%) | PolyPhen probably damaging (0.994); called by muse, mutect2
- UBQLN3 | c.1535A>G p.Q512R | Missense Mutation (SNP) | VAF 36/274 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- UGT2A2 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- UNC79 | c.3873T>A p.D1291E (on ENST00000393151 / NM_001346218.2; = p.D1114E on NM_020818.5) | Missense Mutation (SNP) | VAF 65/315 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- URB2 | c.126+1_126+5del p.X42_splice | Splice Site (DEL) | VAF 14/94 reads (15%) | called by mutect2, pindel
- USH2A | c.14932G>T p.D4978Y | Missense Mutation (SNP) | VAF 48/236 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- USH2A | c.12295A>C p.T4099P | Missense Mutation (SNP) | VAF 62/358 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- USP24 | c.2783T>A p.L928Q | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- USP45 | c.1531G>C p.E511Q | Missense Mutation (SNP) | VAF 35/392 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.864); called by muse, mutect2
- ZFC3H1 | c.2942A>G p.Q981R | Missense Mutation (SNP) | VAF 95/195 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ZFHX3 | c.594C>G p.F198L | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2
- ZMYM3 | c.848G>T p.R283L | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ZNF347 | c.2350C>T p.Q784* | Nonsense Mutation (SNP) | VAF 11/153 reads (7%) | called by muse, mutect2
- ZNF649 | c.818G>A p.R273K | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (0.88); PolyPhen benign (0.007); called by muse, mutect2
- ZNF721 | c.977G>C p.C326S (on ENST00000338977; = p.C338S on NM_133474.4) | Missense Mutation (SNP) | VAF 10/342 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- ZNF831 | c.1447C>A p.L483I | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.314); called by muse, mutect2
- ZSWIM2 | c.672G>C p.E224D | Missense Mutation (SNP) | VAF 30/295 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- AKR7L | c.579C>T p.F193= | Silent (SNP) | VAF 105/479 reads (22%) | called by muse, mutect2, varscan2
- ARHGAP21 | c.3351A>G p.P1117= | Silent (SNP) | VAF 44/134 reads (33%) | catalogued as rs745676132; called by muse, mutect2, varscan2
- ARHGAP31 | c.3753T>A p.S1251= | Silent (SNP) | VAF 76/284 reads (27%) | called by muse, mutect2, varscan2
- ARL6IP4 | c.228G>A p.E76= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs756298215; called by muse, mutect2, varscan2
- ARMCX4 | c.489C>A p.A163= (on ENST00000433011; = p.A59= on NM_001256155.2) | Silent (SNP) | VAF 40/343 reads (12%) | called by muse, mutect2, varscan2
- ATP11C | c.1098A>C p.V366= | Silent (SNP) | VAF 22/181 reads (12%) | called by muse, mutect2, varscan2
- B4GALNT4 | c.2115C>T p.C705= | Silent (SNP) | VAF 15/170 reads (9%) | called by muse, mutect2
- C4orf54 | c.351C>G p.L117= | Silent (SNP) | VAF 38/170 reads (22%) | called by muse, mutect2, varscan2
- CALHM3 | c.768G>A p.A256= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as rs539780804; called by muse, mutect2, varscan2
- CARD6 | c.1812A>T p.P604= | Silent (SNP) | VAF 28/440 reads (6%) | called by muse, mutect2
- CDH16 | c.750C>T p.L250= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as rs764318192, COSV55339576; called by muse, mutect2, varscan2
- CNTNAP2 | c.1920G>T p.V640= | Silent (SNP) | VAF 73/349 reads (21%) | called by muse, mutect2, varscan2
- CPS1 | c.2934G>C p.V978= | Silent (SNP) | VAF 18/199 reads (9%) | called by muse, mutect2
- CTDP1 | c.2292G>A p.K764= | Silent (SNP) | VAF 84/568 reads (15%) | called by muse, mutect2, varscan2
- DEPTOR | c.1179G>A p.L393= | Silent (SNP) | VAF 27/400 reads (7%) | catalogued as COSV99638180; called by muse, mutect2
- DIAPH2 | c.582G>T p.P194= | Silent (SNP) | VAF 35/184 reads (19%) | catalogued as rs201709490; called by muse, mutect2, varscan2
- DNAH5 | c.951G>T p.A317= | Silent (SNP) | VAF 84/630 reads (13%) | catalogued as COSV99447175; called by muse, mutect2, varscan2
- DOK5 | c.768G>A p.S256= | Silent (SNP) | VAF 16/348 reads (5%) | catalogued as rs1446608438, COSV52824067; called by muse, mutect2
- FAM90A14P | c.768C>A p.P256= | Silent (SNP) | VAF 52/969 reads (5%) | called by muse, mutect2
- FAM90A26 | c.213G>T p.P71= | Silent (SNP) | VAF 36/1016 reads (4%) | called by muse, mutect2
- GJC2 | c.270C>G p.P90= | Silent (SNP) | VAF 18/377 reads (5%) | catalogued as rs12075149; called by muse, mutect2
- HFM1 | c.3594G>A p.Q1198= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs776993117, COSV99645079; called by muse, mutect2, varscan2
- IDS | c.27C>G p.G9= | Silent (SNP) | VAF 19/83 reads (23%) | called by muse, mutect2, varscan2
- KDM4C | c.2826C>T p.V942= | Silent (SNP) | VAF 20/243 reads (8%) | catalogued as rs374431440; called by muse, mutect2
- LAMA3 | c.2562A>G p.G854= | Silent (SNP) | VAF 167/468 reads (36%) | called by muse, mutect2, varscan2
- LOXHD1 | c.1021C>A p.R341= | Silent (SNP) | VAF 73/367 reads (20%) | catalogued as rs931911802; called by muse, mutect2, varscan2
- LRRC66 | c.1324C>T p.L442= | Silent (SNP) | VAF 16/327 reads (5%) | called by muse, mutect2
- LYSMD3 | c.372A>G p.P124= | Silent (SNP) | VAF 81/205 reads (40%) | called by muse, mutect2, varscan2
- MRRF | c.27C>T p.R9= | Silent (SNP) | VAF 18/286 reads (6%) | called by muse, mutect2
- MUC17 | c.6351T>A p.P2117= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as rs371476183; called by muse, mutect2, varscan2
- MUC17 | c.6666C>T p.F2222= | Silent (SNP) | VAF 29/238 reads (12%) | called by muse, mutect2, varscan2
- MUC2 | c.186C>A p.P62= | Silent (SNP) | VAF 20/78 reads (26%) | called by muse, mutect2, varscan2
- MYT1L | c.1071C>T p.I357= | Silent (SNP) | VAF 91/365 reads (25%) | catalogued as rs1322793511; called by muse, mutect2, varscan2
- NBPF6 | c.1597C>T p.L533= | Silent (SNP) | VAF 102/309 reads (33%) | called by muse, mutect2, varscan2
- NCAPD3 | c.1020C>T p.A340= | Silent (SNP) | VAF 25/90 reads (28%) | called by muse, mutect2, varscan2
- NR1H4 | c.48T>A p.P16= | Silent (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
- NXPE3 | c.1311C>T p.N437= | Silent (SNP) | VAF 24/366 reads (7%) | called by muse, mutect2
- OGT | c.2142C>T p.H714= | Silent (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- OR5B17 | c.144G>T p.L48= | Silent (SNP) | VAF 50/234 reads (21%) | catalogued as COSV62160078; called by muse, mutect2, varscan2
- OR8I2 | c.456C>A p.G152= | Silent (SNP) | VAF 82/265 reads (31%) | called by muse, mutect2, varscan2
- PCDHB4 | c.1818C>G p.L606= | Silent (SNP) | VAF 168/692 reads (24%) | catalogued as COSV52027979; called by muse, mutect2, varscan2
- PPP1R3F | c.652C>T p.L218= | Silent (SNP) | VAF 26/657 reads (4%) | catalogued as rs1350387900; called by muse, mutect2
- RBM15B | c.45C>A p.G15= | Silent (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- RTTN | c.957A>C p.T319= | Silent (SNP) | VAF 41/197 reads (21%) | called by muse, mutect2, varscan2
- RYR3 | c.14568C>A p.A4856= (on ENST00000389232; = p.A4857= on NM_001036.6) | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as COSV100145761; called by muse, mutect2, varscan2
- SBSPON | c.343C>T p.L115= | Silent (SNP) | VAF 20/169 reads (12%) | catalogued as rs375795680; called by muse, mutect2, varscan2
- SERPINC1 | c.777A>T p.S259= | Silent (SNP) | VAF 55/193 reads (28%) | called by muse, mutect2, varscan2
- SLC24A2 | c.1377C>T p.L459= | Silent (SNP) | VAF 33/402 reads (8%) | catalogued as rs776781506; called by muse, mutect2
- SMIM20 | c.57T>C p.S19= | Silent (SNP) | VAF 28/148 reads (19%) | catalogued as rs1560385004; called by muse, mutect2, varscan2
- SPATA31A6 | c.3330G>A p.R1110= | Silent (SNP) | VAF 254/912 reads (28%) | catalogued as rs748988944; called by muse, mutect2, varscan2
- STOML1 | c.696G>T p.G232= | Silent (SNP) | VAF 33/98 reads (34%) | called by muse, mutect2, varscan2
- TG | c.4899A>T p.T1633= | Silent (SNP) | VAF 108/564 reads (19%) | called by muse, mutect2, varscan2
- TICRR | c.90C>T p.L30= | Silent (SNP) | VAF 27/322 reads (8%) | called by muse, mutect2
- TIMP1 | c.276C>A p.V92= | Silent (SNP) | VAF 19/119 reads (16%) | called by muse, mutect2, varscan2
- TNIP3 | c.231G>A p.T77= | Silent (SNP) | VAF 89/271 reads (33%) | catalogued as rs757586748, COSV50247852, COSV50248802; called by muse, mutect2, varscan2
- TRHDE | c.2823G>A p.R941= | Silent (SNP) | VAF 43/272 reads (16%) | called by muse, mutect2, varscan2
- TWSG1 | c.204C>T p.D68= | Silent (SNP) | VAF 25/243 reads (10%) | catalogued as rs145134563; called by muse, mutect2, varscan2
- TYR | c.744A>G p.T248= | Silent (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- UGT2B10 | c.1518C>T p.I506= | Silent (SNP) | VAF 46/211 reads (22%) | catalogued as COSV55323562; called by muse, mutect2, varscan2
- ULK1 | c.2205G>T p.G735= | Silent (SNP) | VAF 35/86 reads (41%) | called by muse, mutect2, varscan2
- VPS13A | c.4395C>G p.V1465= | Silent (SNP) | VAF 10/123 reads (8%) | called by muse, mutect2
- ZBED1 | c.1071G>T p.T357= | Silent (SNP) | VAF 133/440 reads (30%) | called by muse, mutect2, varscan2
- ZFYVE28 | c.1746G>T p.R582= | Silent (SNP) | VAF 54/250 reads (22%) | called by muse, mutect2, varscan2
- ZKSCAN1 | c.1401G>A p.G467= | Silent (SNP) | VAF 29/173 reads (17%) | catalogued as rs1359945980; called by muse, mutect2, varscan2
- ZNF462 | c.6864G>T p.R2288= | Silent (SNP) | VAF 62/135 reads (46%) | called by muse, mutect2, varscan2
- ZNF606 | c.330C>T p.V110= | Silent (SNP) | VAF 9/183 reads (5%) | called by muse, mutect2
- ZNF831 | c.1446C>A p.P482= | Silent (SNP) | VAF 24/76 reads (32%) | called by muse, mutect2
- AC092329.3 | c.-211-534G>T | Intron (SNP) | VAF 18/176 reads (10%) | called by muse, mutect2
- AL132655.6 | chr20:58840272 G>T | 5'Flank (SNP) | VAF 203/692 reads (29%) | called by muse, mutect2, varscan2
- AL590617.2 | n.1664G>T | RNA (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- ANK2 | c.-41C>A | 5'UTR (SNP) | VAF 26/160 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP23P1 | chr16:33938357 G>T | 5'Flank (SNP) | VAF 19/138 reads (14%) | called by muse, mutect2, varscan2
- ARHGAP40 | c.*506C>T | 3'UTR (SNP) | VAF 20/288 reads (7%) | catalogued as rs1307834873, COSV54807429; called by muse, mutect2
- C5orf17 | n.206T>A | RNA (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- CALR3 | c.*25A>C | 3'UTR (SNP) | VAF 20/218 reads (9%) | called by muse, mutect2
- CCDC102B | c.1263+189C>A | Intron (SNP) | VAF 32/147 reads (22%) | catalogued as COSV100103810; called by muse, varscan2
- COPG1 | c.-2C>T | 5'UTR (SNP) | VAF 17/202 reads (8%) | catalogued as rs1401516966; called by muse, mutect2
- DGKD | c.2580+182G>A | Intron (SNP) | VAF 18/226 reads (8%) | called by muse, mutect2
- DMPK | c.161-457A>G | Intron (SNP) | VAF 10/35 reads (29%) | catalogued as rs1472441950; called by muse, mutect2, varscan2
- DSCAM | c.-26G>T | 5'UTR (SNP) | VAF 5/9 reads (56%) | catalogued as COSV68632618; called by muse, mutect2, varscan2
- EMX2 | c.-33T>A | 5'UTR (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
- ERC1 | c.2487+7706C>T | Intron (SNP) | VAF 7/187 reads (4%) | called by muse, mutect2
- FAM161A | c.184-4588C>T | Intron (SNP) | VAF 42/130 reads (32%) | catalogued as rs896226009; called by muse, mutect2, varscan2
- FAM90A27P | n.839A>C | RNA (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
- GATD1 | c.545-87G>A | Intron (SNP) | VAF 78/222 reads (35%) | called by muse, mutect2, varscan2
- GLDC | c.-49G>C | 5'UTR (SNP) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- GOLGA8IP | chr15:22617765 G>T | 5'Flank (SNP) | VAF 85/279 reads (30%) | called by muse, mutect2, varscan2
- HEG1 | c.1589-871C>T | Intron (SNP) | VAF 60/184 reads (33%) | called by muse, mutect2, varscan2
- HERC2P3 | n.349T>A | RNA (SNP) | VAF 40/328 reads (12%) | called by muse, mutect2, varscan2
- HUWE1 | c.8206+109G>T | Intron (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- IRF1 | c.414+24G>A | Intron (SNP) | VAF 84/200 reads (42%) | called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847280 A>T | 5'Flank (SNP) | VAF 13/280 reads (5%) | called by muse, mutect2
- KRBOX4 | c.253+54G>C | Intron (SNP) | VAF 53/323 reads (16%) | called by muse, mutect2, varscan2
- KRT17P1 | n.514A>T | RNA (SNP) | VAF 38/514 reads (7%) | called by muse, mutect2
- KRT5 | c.-47C>G | 5'UTR (SNP) | VAF 43/225 reads (19%) | catalogued as COSV99357825; called by muse, mutect2, varscan2
- LINC02694 | n.351C>A | RNA (SNP) | VAF 53/160 reads (33%) | called by muse, mutect2, varscan2
- NOL4L-DT | n.352G>T | RNA (SNP) | VAF 132/374 reads (35%) | called by muse, mutect2, varscan2
- PAX8 | c.-86G>T | 5'UTR (SNP) | VAF 41/218 reads (19%) | called by muse, mutect2, varscan2
- PIGQ | c.821+44C>G | Intron (SNP) | VAF 47/311 reads (15%) | called by muse, mutect2, varscan2
- PIM1 | c.608-346C>G | Intron (SNP) | VAF 74/420 reads (18%) | called by muse, mutect2, varscan2
- PPP3CA | c.259+24737G>C | Intron (SNP) | VAF 13/156 reads (8%) | called by muse, mutect2
- PQBP1 | c.-51G>C | 5'UTR (SNP) | VAF 23/274 reads (8%) | called by muse, mutect2
- PTGER3 | c.*24-12955C>T | Intron (SNP) | VAF 32/123 reads (26%) | called by muse, mutect2, varscan2
- RPGR | c.2520+681_2520+682del | Intron (DEL) | VAF 7/16 reads (44%) | called by mutect2, varscan2
- RSPO4 | c.-36C>T | 5'UTR (SNP) | VAF 129/380 reads (34%) | catalogued as rs768594197; called by muse, mutect2, varscan2
- SLC13A4 | chr7:135728944 G>T | 5'Flank (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- SLC25A14 | c.594+360G>T | Intron (SNP) | VAF 51/172 reads (30%) | called by muse, mutect2, varscan2
- SLC26A5 | c.-27G>T | 5'UTR (SNP) | VAF 82/249 reads (33%) | catalogued as COSV100099927; called by muse, mutect2, varscan2
- TLL1 | c.*42G>T | 3'UTR (SNP) | VAF 58/177 reads (33%) | called by muse, mutect2, varscan2
- TRIML2 | c.746-846C>A | Intron (SNP) | VAF 14/117 reads (12%) | catalogued as rs529071248; called by muse, mutect2, varscan2
- UBE2DNL | n.531G>T | RNA (SNP) | VAF 41/162 reads (25%) | called by muse, mutect2, varscan2
- VSIG4 | c.962+29G>C | Intron (SNP) | VAF 24/99 reads (24%) | called by muse, mutect2, varscan2
- ZNF503 | c.-76C>T | 5'UTR (SNP) | VAF 44/278 reads (16%) | called by muse, varscan2
- ZNF503 | c.-77G>T | 5'UTR (SNP) | VAF 44/280 reads (16%) | called by muse, varscan2
- ZNF773 | chr19:57513049 C>A | 3'Flank (SNP) | VAF 26/142 reads (18%) | called by muse, mutect2, varscan2
